Surgical pathology report (de-identified scan), TCGA case TCGA-CR-6482, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Vanderbilt University, specimen TCGA-CR-6482-01A (Primary Tumor).

SURGICAL PATHOLOGY REPORT

Accession number: [REDACTED]

Final Report

DIAGNOSIS:

1) TONSIL, LEFT, BIOPSY: INVASIVE POORLY DIFFERENTIATED SQUAMOUS CELL CARCINOMA, BASALOID-TYPE.

**Electronically Signed Out by [REDACTED]

CLINICAL DATA

Clinical Features: Unspecified

Operator: [REDACTED]

Operation: Direct laryngoscopy with biopsy

Operative Findings: Left tonsil lesion

Operative Diagnosis: Unspecified

Tissue Submitted: 1) left tonsil biopsy

GROSS DESCRIPTION:

1) SOURCE: Left Tonsil Biopsy

Received fresh labeled with the patient's name and "left tonsil biopsy" are multiple pink soft irregular tissue fragments measuring 1.5 x 1.0 x 0.3 cm in aggregate. This tissue is submitted entirely.

Summary of sections: 1A, M/1.

Dictated by [REDACTED]

Slides and report reviewed by Attending Pathologist.

[REDACTED]

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 039daea0-b2fd-42c8-971a-6b1081610f1f (TCGA-CR-6482.86631A72-6BAE-424F-B38F-528E30F7F652.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).